CCDI case PBCVYM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/f3a545e3-cda1-4e69-878d-b4451470dee6

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1AFO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1AG0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1YI4: Tissue type: Tumor; Specimen type: Solid Tissue.
